Somatic mutation profile of tumor specimen C3N-00872-02 (aliquot CPT0116250007) from CPTAC case C3N-00872, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage I; FIGO stage: Stage I; Tumor grade: G1; Age at diagnosis: 75.3 years (27,503 days).
Specimen C3N-00872-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ef4f9d59-7c4e-460b-aea3-0147c4b510c5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-00872-31 (Blood Derived Normal), aliquot CPT0116330002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/92084f1f-d354-4951-a9fd-7090cacd0d56

The open-access MAF lists 79 somatic variants for this specimen: 52 protein-altering or splice-affecting, 21 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 43, Silent 21, Intron 5, Nonsense Mutation 4, Frame Shift Del 3, Splice Site 1, In Frame Del 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACVR1 | c.605G>T p.R202I | Missense Mutation (SNP) | VAF 43/369 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs387906591, CM091832, COSV55123617; ClinVar: pathogenic; called by muse, varscan2
- FGFR2 | c.755C>G p.S252W | Missense Mutation (SNP) | VAF 28/113 reads (25%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs79184941, CM950458, CM970526, COSV60638319; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.376G>A p.A126T | Missense Mutation (SNP) | VAF 198/430 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1554898129, CM110132, COSV64288974, COSV64292774, COSV64296979; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ACAD10 | c.2501G>A p.R834H | Missense Mutation (SNP) | VAF 61/201 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.052); catalogued as rs932721321, COSV58155123; called by muse, mutect2, varscan2
- ACTRT1 | c.112G>A p.V38I | Missense Mutation (SNP) | VAF 36/175 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.031); catalogued as rs138725538, COSV64418994; called by muse, mutect2, varscan2
- APCS | c.415C>T p.R139* | Nonsense Mutation (SNP) | VAF 49/235 reads (21%) | catalogued as rs879661012, COSV54817191; called by muse, mutect2, varscan2
- ARID1A | c.2248C>T p.R750* | Nonsense Mutation (SNP) | VAF 47/205 reads (23%) | catalogued as COSV100250607, COSV61371935; called by muse, mutect2, varscan2
- CCDC134 | c.616C>T p.R206C | Missense Mutation (SNP) | VAF 41/177 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs144065271; called by muse, mutect2, varscan2
- CERS4 | c.248C>T p.T83M | Missense Mutation (SNP) | VAF 85/399 reads (21%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.602); catalogued as rs771555829; called by muse, mutect2, varscan2
- CXorf58 | c.595G>A p.G199S | Missense Mutation (SNP) | VAF 17/149 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs780368307, COSV64858042; called by muse, mutect2, varscan2
- DHX30 | c.886C>T p.R296C (on ENST00000445061 / NM_138615.3; = p.R257C on NM_014966.3) | Missense Mutation (SNP) | VAF 98/383 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.799); catalogued as rs970979901; called by muse, mutect2, varscan2
- EP400 | c.3989G>A p.R1330H | Missense Mutation (SNP) | VAF 19/165 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.034); catalogued as rs777854609, COSV57787370; called by muse, mutect2, varscan2
- GLP1R | c.977G>A p.R326Q | Missense Mutation (SNP) | VAF 51/221 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as rs1352145873; called by muse, mutect2, varscan2
- KDM6A | c.308A>G p.N103S | Missense Mutation (SNP) | VAF 33/137 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs749202669; called by muse, mutect2, varscan2
- KLHL25 | c.397C>T p.R133W | Missense Mutation (SNP) | VAF 80/377 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs77624363; called by muse, mutect2, varscan2
- LIN37 | c.637C>T p.R213C | Missense Mutation (SNP) | VAF 18/437 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.198); catalogued as COSV50000638; called by muse, mutect2
- MAP1B | c.5902G>A p.E1968K | Missense Mutation (SNP) | VAF 10/175 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.14); catalogued as rs999621263, COSV57095515, COSV99702129; called by muse, mutect2
- MED12 | c.67G>T p.D23Y | Missense Mutation (SNP) | VAF 93/282 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61334558; called by muse, mutect2, varscan2
- MLLT1 | c.340G>C p.V114L | Missense Mutation (SNP) | VAF 83/333 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.863); catalogued as COSV53129959, COSV53130123; called by muse, mutect2, varscan2
- MMP2 | c.1099G>A p.G367S | Missense Mutation (SNP) | VAF 102/423 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748528474; called by muse, mutect2, varscan2
- MYO15A | c.9601C>T p.R3201W | Missense Mutation (SNP) | VAF 119/523 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.971); catalogued as rs753745652; called by muse, mutect2, varscan2
- PGR | c.1896G>A p.M632I | Missense Mutation (SNP) | VAF 75/313 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV54800565; called by muse, mutect2, varscan2
- RERGL | c.176del p.P59Lfs*40 | Frame Shift Del (DEL) | VAF 14/96 reads (15%) | catalogued as rs761260726; called by mutect2, pindel, varscan2
- RNF43 | c.686C>T p.P229L | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.388); catalogued as rs763974538, COSV68459639; called by muse, mutect2, varscan2
- SARDH | c.1523C>T p.P508L | Missense Mutation (SNP) | VAF 69/269 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as rs766600569; called by muse, mutect2, varscan2
- SMARCA1 | c.125C>T p.A42V | Missense Mutation (SNP) | VAF 66/317 reads (21%) | SIFT tolerated (0.3); PolyPhen benign (0.013); catalogued as COSV64414190; called by muse, mutect2, varscan2
- SRM | c.661C>T p.R221W | Missense Mutation (SNP) | VAF 29/88 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.027); catalogued as rs775399258, COSV65384866; called by muse, mutect2, varscan2
- TDRD15 | c.358C>T p.R120W | Missense Mutation (SNP) | VAF 64/206 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1224425954; called by muse, mutect2, varscan2
- TEPSIN | c.1297G>A p.E433K | Missense Mutation (SNP) | VAF 21/199 reads (11%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as rs1309049007; called by muse, mutect2, varscan2
- TMEM184C | c.1084T>A p.L362M | Missense Mutation (SNP) | VAF 42/126 reads (33%) | SIFT tolerated (0.25); PolyPhen benign (0.039); catalogued as rs549244997; called by muse, varscan2
- TNMD | c.634del p.E212Kfs*16 | Frame Shift Del (DEL) | VAF 27/136 reads (20%) | catalogued as COSV100887810; called by mutect2, pindel, varscan2
- USP10 | c.1444C>T p.R482* | Nonsense Mutation (SNP) | VAF 45/185 reads (24%) | catalogued as rs757444995; called by muse, mutect2, varscan2
- ZNF791 | c.1436_1438del p.C479del | In Frame Del (DEL) | VAF 30/166 reads (18%) | catalogued as rs551257912; called by pindel, varscan2
- ARHGEF37 | c.1403G>T p.S468I | Missense Mutation (SNP) | VAF 35/153 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.165); called by muse, mutect2, varscan2
- CAMTA2 | c.1864C>G p.L622V | Missense Mutation (SNP) | VAF 85/265 reads (32%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- CDH18 | c.1370C>A p.T457K | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- CSMD3 | c.22G>C p.E8Q | Missense Mutation (SNP) | VAF 36/402 reads (9%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.011); called by muse, mutect2
- CTNND1 | c.2265G>C p.L755F (on ENST00000399050 / NM_001085458.2; = p.L749F on NM_001331.3) | Missense Mutation (SNP) | VAF 10/119 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- DTWD2 | c.848_849del p.K283Tfs*12 | Frame Shift Del (DEL) | VAF 70/280 reads (25%) | called by mutect2, pindel, varscan2
- ENOX2 | c.851G>A p.R284H (on ENST00000338144 / NM_001382520.1; = p.R255H on NM_006375.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 40/390 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); called by muse, mutect2
- GOLPH3 | c.530T>G p.L177* | Nonsense Mutation (SNP) | VAF 62/181 reads (34%) | called by muse, mutect2, varscan2
- GRHL1 | c.21-26_42del p.X7_splice | Splice Site (DEL) | VAF 34/254 reads (13%) | called by mutect2, pindel
- HSD17B6 | c.85G>T p.D29Y | Missense Mutation (SNP) | VAF 38/163 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.261); called by muse, mutect2, varscan2
- IREB2 | c.2335C>T p.R779C | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- MCCC1 | c.581A>T p.H194L | Missense Mutation (SNP) | VAF 137/563 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.158); called by muse, mutect2, varscan2
- MTRF1 | c.418C>G p.L140V | Missense Mutation (SNP) | VAF 31/104 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.294); called by muse, mutect2, varscan2
- NLRP3 | c.1253C>A p.T418N | Missense Mutation (SNP) | VAF 93/362 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); called by muse, mutect2, varscan2
- NUP98 | c.4295T>G p.L1432R (on ENST00000359171 / NM_001365126.1; = p.L1415R on NM_016320.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 66/313 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- SETD2 | c.4853C>T p.T1618I | Missense Mutation (SNP) | VAF 14/153 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLITRK5 | c.593G>A p.R198H | Missense Mutation (SNP) | VAF 13/393 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); called by muse, mutect2
- TFB1M | c.764T>C p.F255S | Missense Mutation (SNP) | VAF 56/492 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.374); called by muse, mutect2, varscan2
- THBS2 | c.1052A>G p.H351R | Missense Mutation (SNP) | VAF 59/253 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ABCG8 | c.627C>T p.Y209= | Silent (SNP) | VAF 50/420 reads (12%) | catalogued as rs756486773; called by muse, mutect2, varscan2
- AMER1 | c.2616C>T p.Y872= | Silent (SNP) | VAF 121/389 reads (31%) | called by muse, mutect2, varscan2
- CARD9 | c.1371C>T p.G457= | Silent (SNP) | VAF 44/210 reads (21%) | catalogued as rs751319751, COSV59996236; called by muse, mutect2, varscan2
- CHD3 | c.1515G>A p.L505= | Silent (SNP) | VAF 57/219 reads (26%) | called by muse, mutect2, varscan2
- GMEB2 | c.1062G>A p.P354= | Silent (SNP) | VAF 22/89 reads (25%) | catalogued as rs199823681; called by muse, mutect2, varscan2
- GPR17 | c.1077C>T p.S359= | Silent (SNP) | VAF 20/123 reads (16%) | called by muse, mutect2, varscan2
- HCN1 | c.2361C>T p.S787= | Silent (SNP) | VAF 35/367 reads (10%) | catalogued as rs758609806, COSV57510971; called by muse, mutect2, varscan2
- IL34 | c.513C>T p.V171= | Silent (SNP) | VAF 27/105 reads (26%) | called by muse, mutect2, varscan2
- KLHDC7B | c.999G>T p.R333= (on ENST00000395676; = p.R974= on NM_138433.5) | Silent (SNP) | VAF 74/204 reads (36%) | called by muse, mutect2, varscan2
- MAGI3 | c.2163C>T p.N721= | Silent (SNP) | VAF 7/155 reads (5%) | called by muse, mutect2
- MGLL | c.513G>A p.L171= (on ENST00000398104 / NM_001003794.2; = p.L181= on NM_007283.6) | Silent (SNP) | VAF 127/489 reads (26%) | catalogued as COSV54022253; called by muse, mutect2, varscan2
- MUC20 | c.1512C>T p.S504= | Silent (SNP) | VAF 139/723 reads (19%) | catalogued as rs769720088, COSV100290859; called by muse, mutect2, varscan2
- NKX2-2 | c.312G>C p.P104= | Silent (SNP) | VAF 46/172 reads (27%) | called by muse, mutect2, varscan2
- OBSCN | c.9876G>A p.T3292= | Silent (SNP) | VAF 50/226 reads (22%) | catalogued as rs1338511116, COSV99484428; called by muse, mutect2, varscan2
- OGT | c.1698G>A p.G566= | Silent (SNP) | VAF 40/204 reads (20%) | called by muse, mutect2, varscan2
- PCDHA2 | c.2229C>T p.S743= | Silent (SNP) | VAF 181/637 reads (28%) | catalogued as rs374379905, COSV65369629; called by muse, mutect2, varscan2
- SLC25A37 | c.756G>A p.T252= | Silent (SNP) | VAF 130/414 reads (31%) | catalogued as COSV99264216; called by muse, mutect2, varscan2
- TMEM150A | c.102T>C p.P34= (on ENST00000334462 / NM_001031738.3; = p.L4P on NM_153342.3) | Silent (SNP) | VAF 63/200 reads (32%) | called by muse, mutect2, varscan2
- TRIO | c.1464G>A p.Q488= | Silent (SNP) | VAF 51/222 reads (23%) | called by muse, mutect2, varscan2
- TRIOBP | c.3738G>A p.P1246= | Silent (SNP) | VAF 57/229 reads (25%) | catalogued as rs376529019, COSV60384108; called by muse, mutect2, varscan2
- ZNF469 | c.6741G>T p.G2247= (on ENST00000437464; = p.G2275= on NM_001367624.2) | Silent (SNP) | VAF 110/831 reads (13%) | called by muse, mutect2, varscan2
- MYH11 | c.4366-39G>A | Intron (SNP) | VAF 98/340 reads (29%) | catalogued as rs373678131; called by muse, mutect2, varscan2
- PARP8 | c.185-2495G>T | Intron (SNP) | VAF 25/143 reads (17%) | called by muse, mutect2, varscan2
- PDCD6 | c.368-42G>A | Intron (SNP) | VAF 79/327 reads (24%) | catalogued as rs540250017; called by muse, mutect2, varscan2
- SOX3 | c.*20C>T | 3'UTR (SNP) | VAF 26/98 reads (27%) | called by muse, mutect2, varscan2
- TJP1 | c.1256+50A>G | Intron (SNP) | VAF 25/119 reads (21%) | called by muse, mutect2, varscan2
- UBE2E3 | c.245+5818A>G | Intron (SNP) | VAF 13/61 reads (21%) | called by muse, mutect2, varscan2
